Somatic mutation profile of tumor specimen TCGA-4V-A9QM-01A (aliquot TCGA-4V-A9QM-01A-11D-A423-09) from TCGA case TCGA-4V-A9QM, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 39.9 years (14,576 days).
Specimen TCGA-4V-A9QM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d8b7a65-3d66-4cb5-8a40-90b5fe202ec7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4V-A9QM-11A (Solid Tissue Normal), aliquot TCGA-4V-A9QM-11A-11D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c5b72bc-ec56-4af7-a4d6-ee9353e912cf

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EEF1AKMT4 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs754085919; called by muse, mutect2, varscan2
- KATNIP | c.3514C>T p.R1172W | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs558540912; called by muse, mutect2, varscan2
- PLCE1 | c.5881C>T p.R1961* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as rs774196868, COSV53371264; called by muse, mutect2, varscan2
- RBM23 | c.338C>T p.S113L (on ENST00000359890 / NM_001077351.2; = p.S97L on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs762429165, COSV57127143; called by muse, mutect2, varscan2
- ALDH16A1 | c.1487G>T p.C496F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- LMTK2 | c.2572A>T p.I858F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MTAP | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- C19orf57 | c.648G>A p.G216= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- EP300 | c.834T>C p.T278= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs375358513; called by muse, mutect2, varscan2
- KCNK15 | c.609C>T p.G203= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
